Somatic mutation profile of tumor specimen TARGET-10-PARBRK-03A (aliquot TARGET-10-PARBRK-03A-01D) from TARGET case TARGET-10-PARBRK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,636 days).
Specimen TARGET-10-PARBRK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89fec3cf-f736-44d0-8c89-563022345a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBRK-10A (Blood Derived Normal), aliquot TARGET-10-PARBRK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6599cf-d494-476c-abe1-05b1d966cef1

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN3 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV55168331; called by muse, mutect2, varscan2
- DLGAP1 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204292888, COSV59797823; called by muse, mutect2, varscan2
- DNAH8 | c.8879G>A p.R2960H | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59438618, COSV59444456; called by muse, mutect2, varscan2
- LYPD6B | c.370C>T p.R124* (on ENST00000409029 / NM_001317004.1; = p.R148* on NM_177964.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/219 reads (49%) | catalogued as rs376779764; called by muse, mutect2, varscan2
- MAP2 | c.4111G>A p.D1371N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as rs1385950050, COSV52287804; called by muse, mutect2, varscan2
- MEIOC | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 119/387 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs866802792, COSV63439783; called by muse, mutect2, varscan2
- MMEL1 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770771638, COSV56520346, COSV99983501; called by muse, mutect2, varscan2
- PRRG3 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64850936; called by muse, mutect2, varscan2
- SMARCA1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 167/689 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64411574; called by muse, mutect2, varscan2
- TUBA3D | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.46); catalogued as rs773370954, COSV58310719; called by muse, mutect2
- ADGRG4 | c.1329C>T p.A443= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs749064564, COSV54953939, COSV54964276; called by muse, varscan2
- GREM1 | c.483A>G p.L161= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs780146359, COSV55714789; called by muse, mutect2, varscan2
- SLAMF6 | c.210C>T p.T70= | Silent (SNP) | VAF 260/570 reads (46%) | catalogued as COSV63586906; called by muse, mutect2, varscan2
- TECPR1 | c.3216G>A p.E1072= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1462402272; called by muse, mutect2
